Somatic mutation profile of tumor specimen TCGA-BR-A4PE-01A (aliquot TCGA-BR-A4PE-01A-31D-A25D-08) from TCGA case TCGA-BR-A4PE, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 68.4 years (24,986 days).
Specimen TCGA-BR-A4PE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 96474bc1-96f4-45fe-947d-4f4075f3e3d3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-A4PE-10A (Blood Derived Normal), aliquot TCGA-BR-A4PE-10A-01D-A25E-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/770855e5-f887-49d9-ae8e-ef3706b8b93c

The open-access MAF lists 230 somatic variants for this specimen: 167 protein-altering or splice-affecting, 55 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 143, Silent 55, Nonsense Mutation 9, Frame Shift Del 6, Splice Site 5, Intron 5, Frame Shift Ins 4, 3'UTR 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AR | c.1847G>A p.R616H | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs754201976, CD942043, CM910043, CM930035, COSV65960551; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MED12 | c.5125C>T p.R1709* | Nonsense Mutation (SNP) | VAF 4/44 reads (9%) | catalogued as rs886041581, COSV99048874; ClinVar: pathogenic; called by muse, mutect2
- SCN2A | c.3892G>T p.E1298* | Nonsense Mutation (SNP) | VAF 31/108 reads (29%) | catalogued as rs1553593030, COSV51848887; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.406C>G p.Q136E | Missense Mutation (SNP) | VAF 25/37 reads (68%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1555526268, CM971503, COSV52676850, COSV52715987, COSV52740951; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCA5 | c.3434C>T p.A1145V | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.87); catalogued as rs763638212, COSV67017916; called by muse, mutect2, varscan2
- ABCA8 | c.3998A>C p.N1333T | Missense Mutation (SNP) | VAF 39/187 reads (21%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.493); catalogued as COSV52207165; called by muse, mutect2, varscan2
- ADAMTS12 | c.3755G>A p.G1252E | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV61270461; called by muse, mutect2, varscan2
- ALOX15 | c.942G>A p.M314I | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT tolerated (0.9); PolyPhen benign (0.029); catalogued as COSV53399321; called by muse, mutect2, varscan2
- ANKS1B | c.607C>T p.R203C | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1269579871, COSV61345301; called by muse, mutect2, varscan2
- APOBEC2 | c.289G>T p.A97S | Missense Mutation (SNP) | VAF 40/189 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as COSV55143157; called by muse, mutect2, varscan2
- ASTN1 | c.2168C>A p.T723N | Missense Mutation (SNP) | VAF 38/79 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as COSV56077242; called by muse, mutect2, varscan2
- ASXL1 | c.3010G>A p.D1004N | Missense Mutation (SNP) | VAF 29/117 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60114493; called by muse, mutect2, varscan2
- ASXL3 | c.3754C>A p.H1252N | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.15); catalogued as COSV52473006; called by muse, mutect2, varscan2
- ATF7IP | c.2448C>A p.F816L | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.994); catalogued as COSV53774235; called by muse, mutect2, varscan2
- ATP10A | c.1799A>C p.K600T | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.953); catalogued as COSV63516230; called by muse, mutect2, varscan2
- ATXN10 | c.764C>T p.T255M | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.136); catalogued as rs149859910; called by muse, mutect2, varscan2
- BIRC7 | c.434C>A p.A145D | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752843916, COSV99416379; called by mutect2, varscan2
- BRINP1 | c.1082G>A p.R361H | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.964); catalogued as rs746081030, COSV56297318; called by muse, mutect2, varscan2
- C10orf90 | c.1085G>A p.W362* | Nonsense Mutation (SNP) | VAF 8/48 reads (17%) | catalogued as rs144291584; called by muse, mutect2, varscan2
- C16orf72 | c.691G>T p.D231Y | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59916579; called by muse, mutect2, varscan2
- C16orf89 | c.226C>T p.R76W | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as rs761975801, COSV60125069; called by muse, mutect2, varscan2
- C1orf216 | c.656G>C p.R219T | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.04); catalogued as COSV52054334, COSV99231479; called by muse, mutect2, varscan2
- CAMSAP1 | c.4299A>G p.I1433M | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as COSV56721775; called by muse, mutect2, varscan2
- CD70 | c.388G>A p.V130M | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as rs548095306, COSV55565708; called by muse, mutect2, varscan2
- CDH13 | c.1558C>A p.P520T | Missense Mutation (SNP) | VAF 27/132 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV51846806; called by muse, mutect2, varscan2
- CDH23 | c.1744C>T p.R582W | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.187); catalogued as rs780571524, COSV54943477; called by muse, mutect2
- CDK13 | c.4156C>G p.H1386D | Missense Mutation (SNP) | VAF 23/124 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.452); catalogued as COSV51703408; called by muse, mutect2, varscan2
- CES2 | c.746G>A p.G249E | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.672); catalogued as COSV57697371; called by muse, mutect2, varscan2
- CFAP65 | c.2068C>T p.R690* | Nonsense Mutation (SNP) | VAF 35/89 reads (39%) | catalogued as rs531146350, COSV58563871; called by muse, mutect2, varscan2
- CHST15 | c.1679C>T p.T560M | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.083); catalogued as rs201459284, COSV60560300; called by mutect2, varscan2
- CLCN7 | c.1613C>T p.A538V | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.014); catalogued as rs548941878, COSV51972145; called by muse, mutect2
- CNTN1 | c.2041G>A p.V681M | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs760051219, COSV61642599; ClinVar: uncertain significance; called by muse, mutect2
- CNTNAP5 | c.2749G>T p.G917W | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70498555; called by muse, mutect2, varscan2
- COL4A1 | c.4796C>T p.A1599V | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as rs766472965, COSV65427582, COSV65429604; called by muse, mutect2, varscan2
- COL5A1 | c.2995G>C p.V999L | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.437); catalogued as COSV65672174; called by muse, mutect2, varscan2
- COL5A3 | c.3922C>A p.P1308T | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.329); catalogued as COSV53415241; called by muse, mutect2, varscan2
- CPNE5 | c.1663G>A p.V555M | Missense Mutation (SNP) | VAF 13/179 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.379); catalogued as rs769712961, COSV55198238; called by muse, mutect2
- CPQ | c.308T>G p.V103G | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55149087; called by muse, mutect2, varscan2
- CSMD1 | c.4319T>G p.F1440C (on ENST00000520002; = p.F1439C on NM_033225.6) | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs746487548, COSV59352106; called by muse, mutect2, varscan2
- CSMD3 | c.4196A>T p.E1399V (on ENST00000297405 / NM_001363185.1; = p.E1295V on NM_052900.3) | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV52144246; called by muse, mutect2, varscan2
- CSPG5 | c.1390C>T p.R464W | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs759344131, COSV53132302; called by muse, mutect2, varscan2
- CTBP2 | c.65G>A p.R22H | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.066); catalogued as rs755005723, COSV58332777; called by muse, mutect2, varscan2
- CTNND2 | c.2966A>C p.K989T | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV58894737, COSV58907551; called by muse, mutect2, varscan2
- CYTH4 | c.355G>A p.D119N | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as rs868185751, COSV50634225; called by mutect2, varscan2
- DAO | c.194+1G>A p.X65_splice | Splice Site (SNP) | VAF 24/116 reads (21%) | catalogued as rs762930737, CS155533, COSV57323690; called by muse, mutect2, varscan2
- DAPK1 | c.2332G>T p.V778L | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.935); catalogued as COSV63789678; called by muse, mutect2, varscan2
- DCLRE1A | c.2597T>G p.V866G | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV63749205; called by muse, mutect2, varscan2
- DGKI | c.2989A>C p.T997P | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55963255; called by muse, mutect2, varscan2
- DRC7 | c.1381C>T p.R461C | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs368843043; called by muse, mutect2, varscan2
- DZIP1 | c.2512C>T p.P838S (on ENST00000347108; = p.P819S on NM_014934.5) | Missense Mutation (SNP) | VAF 29/150 reads (19%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.541); catalogued as COSV61267748; called by muse, mutect2, varscan2
- EPHB1 | c.408A>C p.K136N | Missense Mutation (SNP) | VAF 24/153 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67666117; called by muse, mutect2, varscan2
- EYS | c.1262A>G p.N421S | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.236); catalogued as rs1189048892, COSV60993600; called by mutect2, varscan2
- FAM83D | c.1667C>T p.T556I | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.049); catalogued as rs372480989, COSV54158234; called by muse, mutect2, varscan2
- FAT3 | c.3112C>T p.L1038F | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53145314; called by muse, mutect2, varscan2
- FER | c.2046C>G p.H682Q | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55298187; called by muse, mutect2, varscan2
- FLG | c.8302G>C p.E2768Q | Missense Mutation (SNP) | VAF 68/1151 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.071); catalogued as COSV64244968, COSV64251414; called by muse, mutect2
- FLG2 | c.6855G>T p.Q2285H | Missense Mutation (SNP) | VAF 49/280 reads (18%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.954); catalogued as COSV66170880; called by muse, mutect2, varscan2
- FLRT2 | c.467G>T p.R156L | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.111); catalogued as rs750040176, COSV58146461; called by muse, mutect2, varscan2
- FOXP2 | c.1718G>T p.W573L | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100646098, COSV63488315; called by muse, mutect2, varscan2
- GFI1B | c.844G>A p.G282R | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs762113108, COSV59745830; called by muse, mutect2, varscan2
- GRID2 | c.88G>A p.G30R | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56234110; called by muse, mutect2, varscan2
- HMCN1 | c.13280T>A p.V4427E | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.681); catalogued as COSV54919901; called by mutect2, varscan2
- HMGB4 | c.201C>A p.D67E | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as COSV53935870; called by muse, mutect2, varscan2
- IL6ST | c.1955G>A p.W652* | Nonsense Mutation (SNP) | VAF 5/17 reads (29%) | catalogued as COSV61142164; called by muse, mutect2, varscan2
- IQCF2 | c.352C>T p.R118* | Nonsense Mutation (SNP) | VAF 24/104 reads (23%) | catalogued as rs562556017, COSV60761700; called by muse, mutect2, varscan2
- ITGAL | c.1444G>A p.A482T | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV63323370; called by muse, mutect2, varscan2
- ITIH5 | c.220C>A p.L74M | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.7); catalogued as COSV56909790; called by muse, mutect2, varscan2
- KCND2 | c.905A>C p.K302T | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58592828, COSV58594921; called by muse, mutect2, varscan2
- KDM3B | c.1769A>C p.D590A | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.04); catalogued as rs1326398498, COSV58693075; called by muse, mutect2, varscan2
- KIAA1549 | c.2015T>C p.L672S | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0.014); catalogued as COSV54321406; called by muse, mutect2, varscan2
- KRT74 | c.155G>T p.S52I | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.563); catalogued as COSV59772374, COSV59772578; called by muse, mutect2, varscan2
- LAIR1 | c.62C>T p.T21M | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.024); catalogued as rs746673117, COSV57308701; called by muse, mutect2, varscan2
- LAMB1 | c.578G>C p.R193P | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55963793; called by muse, mutect2, varscan2
- LGR4 | c.1418T>A p.F473Y | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.824); catalogued as COSV64865233; called by muse, mutect2, varscan2
- LMF1 | c.1672G>T p.D558Y | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.232); catalogued as COSV99234421; called by muse, mutect2, varscan2
- LMNA | c.1488+2T>G p.X496_splice | Splice Site (SNP) | VAF 6/52 reads (12%) | catalogued as COSV61543512; called by muse, mutect2
- LMNTD1 | c.107T>G p.L36W | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.027); catalogued as COSV51448969; called by muse, mutect2, varscan2
- LRP1B | c.13295A>G p.K4432R | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.98); catalogued as rs1295002871, COSV67250116; called by muse, mutect2, varscan2
- LRP8 | c.2096G>A p.G699D | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV60100067; called by muse, mutect2, varscan2
- LRRTM3 | c.918C>A p.D306E | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.365); catalogued as COSV63668896; called by muse, mutect2, varscan2
- MAEL | c.908+1G>A p.X303_splice | Splice Site (SNP) | VAF 10/53 reads (19%) | catalogued as rs757249676, COSV63305723; called by muse, mutect2, varscan2
- MAS1 | c.953C>T p.T318M | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.154); catalogued as rs148082809, COSV53121769; called by muse, mutect2, varscan2
- MC3R | c.644G>A p.R215Q | Missense Mutation (SNP) | VAF 9/103 reads (9%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as COSV54763876, COSV54764439; called by muse, mutect2
- MORC1 | c.1598C>A p.P533Q | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51717613, COSV99224793; called by muse, mutect2, varscan2
- MTF1 | c.1529C>T p.A510V | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs750186282, COSV65989873; called by muse, mutect2, varscan2
- MUC6 | c.5740del p.T1914Lfs*71 | Frame Shift Del (DEL) | VAF 150/796 reads (19%) | catalogued as COSV101424875; called by mutect2, pindel, varscan2
- MYH9 | c.4670G>A p.R1557Q | Missense Mutation (SNP) | VAF 32/131 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs373393111, CM101453; called by muse, mutect2, varscan2
- NALCN | c.2579+1G>A p.X860_splice | Splice Site (SNP) | VAF 11/70 reads (16%) | catalogued as rs1020999876, COSV51930302; called by muse, mutect2, varscan2
- NCAN | c.3738A>T p.E1246D | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.027); catalogued as COSV99386317; called by muse, mutect2, varscan2
- NIPSNAP2 | c.232+5_232+8del p.X78_splice | Splice Site (DEL) | VAF 18/119 reads (15%) | catalogued as rs757966247; called by pindel, varscan2
- NKD1 | c.1057G>A p.G353S | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as rs1279368584, COSV51689960, COSV51692738; called by muse, mutect2, varscan2
- NLRP7 | c.2309G>A p.G770D (on ENST00000340844 / NM_206828.3; = p.G742D on NM_139176.3) | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.071); catalogued as COSV60177921; called by muse, mutect2, varscan2
- OBSL1 | c.2056G>A p.V686I | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.246); catalogued as rs202040862; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ONECUT3 | c.1165C>A p.Q389K | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.116); catalogued as COSV101210589; called by muse, mutect2, varscan2
- OPRK1 | c.940T>G p.F314V | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.168); catalogued as COSV55571585; called by muse, varscan2
- OR10J3 | c.353T>C p.V118A | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT tolerated (0.86); PolyPhen benign (0.007); catalogued as rs908365361, COSV59953731; called by muse, mutect2, varscan2
- OR10Z1 | c.265dup p.D89Gfs*23 | Frame Shift Ins (INS) | VAF 34/194 reads (18%) | catalogued as rs752054889; called by mutect2, varscan2
- OR2G2 | c.390C>A p.C130* | Nonsense Mutation (SNP) | VAF 29/176 reads (16%) | catalogued as COSV100189658, COSV100189982, COSV60741391; called by muse, mutect2, varscan2
- OR4A5 | c.100T>G p.L34V | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); catalogued as COSV100157107, COSV60523528; called by muse, mutect2, varscan2
- OR5D18 | c.437T>G p.V146G | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV100450890, COSV61737992; called by muse, mutect2, varscan2
- OSBPL3 | c.1118C>G p.P373R | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.805); catalogued as rs149871533, COSV57659682; called by muse, mutect2, varscan2
- PCARE | c.974T>A p.L325Q | Missense Mutation (SNP) | VAF 27/119 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100527943, COSV59056194; called by muse, mutect2, varscan2
- PHACTR2 | c.1139C>T p.T380M | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.253); catalogued as rs772344848, COSV59856599; called by muse, mutect2, varscan2
- PHYHIP | c.529G>A p.G177S | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.311); catalogued as rs1212723461, COSV58689056; called by muse, mutect2
- PIK3CG | c.1079A>G p.K360R | Missense Mutation (SNP) | VAF 24/142 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV63250883; called by muse, mutect2, varscan2
- PLCD4 | c.2206T>G p.S736A | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV68744578; called by muse, mutect2, varscan2
- PLEKHG3 | c.455G>A p.R152Q (on ENST00000394691; = p.R208Q on NM_001308147.2) | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); catalogued as rs780468802, COSV55981743; called by muse, mutect2, varscan2
- PNMA8B | c.1100A>G p.D367G | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.175); catalogued as COSV66537234; called by muse, mutect2, varscan2
- PREX2 | c.1116A>C p.Q372H | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as COSV55786567; called by muse, mutect2, varscan2
- PRMT6 | c.413G>T p.G138V | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV63655972; called by muse, mutect2, varscan2
- PRPF4 | c.1187G>A p.G396E (on ENST00000374198 / NM_001322267.2; = p.G397E on NM_004697.5) | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65253125; called by muse, mutect2, varscan2
- PRRC2A | c.4051G>A p.V1351M | Missense Mutation (SNP) | VAF 19/150 reads (13%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.005); catalogued as COSV65688005; called by muse, mutect2, varscan2
- PSCA | c.224T>G p.I75S | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.324); catalogued as COSV56653232; called by muse, mutect2, varscan2
- RALBP1 | c.128G>A p.R43H | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.055); catalogued as rs371220710; called by muse, mutect2, varscan2
- RALBP1 | c.686G>A p.G229D | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV50037045; called by muse, mutect2, varscan2
- RHBDD1 | c.683del p.P228Qfs*41 | Frame Shift Del (DEL) | VAF 30/100 reads (30%) | catalogued as rs765161134; called by mutect2, pindel, varscan2
- RP1L1 | c.2402A>G p.Q801R | Missense Mutation (SNP) | VAF 18/218 reads (8%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV66757803; called by muse, mutect2
- RYR3 | c.2891A>G p.K964R | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.404); catalogued as COSV66801022; called by muse, mutect2, varscan2
- SALL4 | c.1055C>T p.A352V | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.278); catalogued as rs754206289, COSV53853514; called by muse, mutect2, varscan2
- SCN3A | c.488G>T p.G163V | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.17); PolyPhen probably damaging (1); catalogued as COSV51817177, COSV99328802; called by muse, mutect2, varscan2
- SERTAD1 | c.8G>A p.S3N | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.122); catalogued as COSV63596004; called by muse, mutect2, varscan2
- SIPA1L1 | c.554T>A p.V185E | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.038); catalogued as COSV62172010; called by muse, mutect2, varscan2
- SIX2 | c.334C>T p.R112C | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1164647831, COSV57391622; called by muse, mutect2, varscan2
- SLC5A12 | c.898C>T p.H300Y | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV54823191, COSV54823962; called by muse, mutect2, varscan2
- SNTN | c.52G>A p.D18N | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.056); catalogued as rs967484680, COSV59538633, COSV59539478; called by muse, mutect2, varscan2
- SORCS3 | c.3094G>C p.A1032P | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.866); catalogued as COSV63796850; called by muse, mutect2, varscan2
- SOS2 | c.1187G>A p.R396H | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as rs770781571, COSV53570846; called by mutect2, varscan2
- SPHKAP | c.4973T>C p.V1658A (on ENST00000392056 / NM_001142644.2; = p.V1629A on NM_030623.3) | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.972); catalogued as COSV100763584; called by muse, mutect2, varscan2
- STAC | c.487C>A p.L163M | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.95); catalogued as COSV56214834; called by muse, mutect2, varscan2
- SUGP1 | c.1276G>A p.G426R | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV55922801; called by muse, mutect2, varscan2
- SVIL | c.820C>T p.R274* | Nonsense Mutation (SNP) | VAF 4/25 reads (16%) | catalogued as COSV63445715; called by muse, mutect2
- SYT3 | c.1672C>T p.R558C | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1190070708, COSV58897930; called by muse, mutect2, varscan2
- TENM4 | c.5854C>T p.R1952C | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.993); catalogued as rs376797038, COSV99580310; called by muse, mutect2, varscan2
- TEX13B | c.218C>T p.A73V | Missense Mutation (SNP) | VAF 41/113 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV57203483; called by muse, mutect2, varscan2
- TEX55 | c.413C>T p.T138M | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.931); catalogued as rs777993427, COSV55210580, COSV99817827; called by muse, mutect2, varscan2
- THSD7A | c.829C>T p.R277C | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.608); catalogued as COSV70260711; called by muse, mutect2, varscan2
- TMCC2 | c.625G>A p.A209T | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.183); catalogued as rs754823714, COSV58005136; called by muse, mutect2, varscan2
- TMEM273 | c.174G>A p.M58I | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV100939561, COSV65152970; called by muse, mutect2, varscan2
- TNK2 | c.1786G>A p.A596T | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.794); catalogued as rs367962373; called by muse, mutect2
- TP73 | c.613G>T p.E205* | Nonsense Mutation (SNP) | VAF 8/26 reads (31%) | catalogued as COSV60704159, COSV60706033; called by muse, mutect2, varscan2
- TPCN1 | c.614G>A p.R205H | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1343889331, COSV59237362; called by muse, mutect2, varscan2
- TRAF3 | c.1260del p.W420* | Frame Shift Del (DEL) | VAF 17/92 reads (18%) | catalogued as COSV61024976; called by mutect2, pindel, varscan2
- TRAV2 | c.266G>A p.R89Q | Missense Mutation (SNP) | VAF 27/147 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.734); catalogued as rs756595595; called by muse, mutect2, varscan2
- TRHDE | c.1774A>T p.T592S | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.913); catalogued as COSV53855176; called by muse, mutect2, varscan2
- TRIO | c.7783G>A p.A2595T | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs369051747; called by muse, mutect2, varscan2
- TRPA1 | c.2672T>C p.L891P | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51568078; called by muse, mutect2, varscan2
- TSNAXIP1 | c.998G>A p.G333D | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745514716, COSV54651071; called by muse, mutect2, varscan2
- TSPYL6 | c.283G>A p.A95T | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.94); PolyPhen benign (0.001); catalogued as rs776617090, COSV57817552; called by muse, mutect2
- TTC25 | c.539C>T p.S180L | Missense Mutation (SNP) | VAF 31/147 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs1403676268, COSV66368699; called by muse, mutect2, varscan2
- TTN | c.62015C>G p.T20672S (on ENST00000591111; = p.T13248S on NM_003319.4) | Missense Mutation (SNP) | VAF 7/59 reads (12%) | PolyPhen benign (0.203); catalogued as COSV60200050; called by muse, mutect2, varscan2
- TTN | c.37283G>A p.R12428Q (on ENST00000591111; = p.R5004Q on NM_003319.4) | Missense Mutation (SNP) | VAF 18/119 reads (15%) | PolyPhen possibly damaging (0.617); catalogued as rs544852574, COSV60089523; called by muse, mutect2, varscan2
- UBN2 | c.686C>T p.S229F | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56033359; called by muse, mutect2, varscan2
- XIRP2 | c.2989G>C p.E997Q (on ENST00000628543; = p.E1172Q on NM_152381.6) | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54717992; called by muse, mutect2, varscan2
- ZBTB38 | c.1690A>G p.K564E | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV58543317; called by muse, mutect2, varscan2
- ZNF12 | c.1160G>A p.G387E (on ENST00000405858 / NM_016265.4; = p.G349E on NM_006956.3) | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.975); catalogued as COSV61245043; called by muse, mutect2, varscan2
- ZNF236 | c.1558G>A p.A520T | Missense Mutation (SNP) | VAF 55/136 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1281289046, COSV53484099; called by muse, mutect2, varscan2
- ZNF517 | c.910C>T p.L304F | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs148736241; called by muse, mutect2, varscan2
- ZNF765 | c.1352C>T p.S451L | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.178); catalogued as COSV67182962; called by muse, mutect2, varscan2
- ZNF804B | c.563G>A p.R188Q | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.051); catalogued as rs775370152, COSV60815815, COSV60824318; called by muse, mutect2, varscan2
- ZNF831 | c.650G>A p.G217E | Missense Mutation (SNP) | VAF 15/118 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.042); catalogued as rs764842217, COSV64042900; called by muse, mutect2, varscan2
- ZSWIM4 | c.844C>T p.R282C | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.335); catalogued as COSV54322442, COSV54324198; called by muse, mutect2, varscan2
- ARID1A | c.4042_4054del p.T1348Afs*129 | Frame Shift Del (DEL) | VAF 32/169 reads (19%) | called by mutect2, pindel, varscan2
- DCDC2B | c.761del p.P254Qfs*33 | Frame Shift Del (DEL) | VAF 16/62 reads (26%) | called by mutect2, pindel, varscan2
- DCLK1 | c.1029_1030insGG p.Q344Gfs*44 | Frame Shift Ins (INS) | VAF 7/47 reads (15%) | called by mutect2, pindel, varscan2
- DMC1 | c.510dup p.R171* | Frame Shift Ins (INS) | VAF 8/47 reads (17%) | called by mutect2, pindel, varscan2
- MUC16 | c.22962dup p.Q7655Sfs*23 | Frame Shift Ins (INS) | VAF 5/31 reads (16%) | called by mutect2, pindel, varscan2
- PCDH15 | c.4910_4911del p.E1637Gfs*6 | Frame Shift Del (DEL) | VAF 14/74 reads (19%) | called by pindel, varscan2
- ACACA | c.4659C>T p.N1553= | Silent (SNP) | VAF 8/71 reads (11%) | called by muse, mutect2, varscan2
- AKNA | c.4284C>T p.R1428= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as COSV56338704; called by muse, mutect2, varscan2
- ARFGAP1 | c.1110C>T p.A370= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as COSV62263549; called by muse, mutect2, varscan2
- ASTE1 | c.1824C>T p.F608= | Silent (SNP) | VAF 23/71 reads (32%) | catalogued as COSV53909487; called by muse, mutect2, varscan2
- ATOH8 | c.285G>A p.E95= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as COSV100092379; called by muse, mutect2
- BRPF1 | c.915C>T p.Y305= | Silent (SNP) | VAF 19/55 reads (35%) | catalogued as rs146224207; called by muse, mutect2, varscan2
- C20orf194 | c.3243G>T p.L1081= | Silent (SNP) | VAF 11/82 reads (13%) | catalogued as COSV52699348; called by muse, mutect2, varscan2
- CACNA2D1 | c.63C>T p.P21= | Silent (SNP) | VAF 9/48 reads (19%) | catalogued as rs746712870, COSV62385859; called by muse, mutect2, varscan2
- CDH8 | c.10C>A p.R4= | Silent (SNP) | VAF 20/63 reads (32%) | catalogued as rs139797882, COSV54872322; ClinVar: likely benign; called by muse, mutect2, varscan2
- CHRNG | c.747C>T p.I249= | Silent (SNP) | VAF 25/160 reads (16%) | catalogued as rs766716676, COSV67315585; called by muse, mutect2, varscan2
- EPHB1 | c.1161G>A p.T387= | Silent (SNP) | VAF 33/63 reads (52%) | catalogued as rs367562212, COSV67665721; called by muse, mutect2, varscan2
- EVA1A | c.252C>T p.S84= | Silent (SNP) | VAF 19/69 reads (28%) | catalogued as rs764114034, COSV52060530; called by muse, mutect2, varscan2
- FAM193A | c.3219G>A p.Q1073= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as COSV61196579; called by muse, mutect2, varscan2
- FASTKD5 | c.2050C>T p.L684= | Silent (SNP) | VAF 22/127 reads (17%) | catalogued as COSV53907601, COSV99418760; called by muse, mutect2, varscan2
- FGD3 | c.972G>A p.A324= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as rs758174304, COSV61596051; called by muse, mutect2, varscan2
- GNPAT | c.903T>G p.P301= | Silent (SNP) | VAF 11/76 reads (14%) | catalogued as COSV64153891; called by muse, mutect2, varscan2
- GSTO1 | c.249C>T p.I83= | Silent (SNP) | VAF 17/58 reads (29%) | catalogued as COSV100866900, COSV63846794; called by muse, mutect2, varscan2
- HEPH | c.471G>A p.P157= (on ENST00000343002; = p.P211= on NM_138737.5) | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as rs771425432, COSV57967829, COSV57968004; called by muse, mutect2, varscan2
- HERC2 | c.5319A>G p.S1773= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as rs1401356684, COSV99870153; called by muse, mutect2, varscan2
- HJURP | c.1137G>A p.V379= | Silent (SNP) | VAF 11/61 reads (18%) | catalogued as rs773177779, COSV64979109; called by muse, mutect2, varscan2
- HOXC4 | c.111C>T p.Y37= | Silent (SNP) | VAF 57/200 reads (29%) | catalogued as rs1451456070, COSV57699663; called by muse, mutect2, varscan2
- HOXD12 | c.630G>A p.T210= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as COSV101184123, COSV66832350; called by muse, mutect2, varscan2
- HS3ST6 | c.633C>T p.H211= | Silent (SNP) | VAF 11/41 reads (27%) | catalogued as rs746937211, COSV53533535; called by muse, mutect2, varscan2
- HTR2C | c.933A>G p.K311= | Silent (SNP) | VAF 24/113 reads (21%) | catalogued as COSV52218928; called by muse, mutect2, varscan2
- INPP5F | c.3093G>A p.A1031= | Silent (SNP) | VAF 32/126 reads (25%) | catalogued as rs760601527, COSV62820017; called by muse, mutect2, varscan2
- KCNH5 | c.786C>A p.I262= | Silent (SNP) | VAF 11/50 reads (22%) | catalogued as COSV59761198, COSV59768519; called by muse, mutect2, varscan2
- KPRP | c.1692C>A p.G564= | Silent (SNP) | VAF 29/57 reads (51%) | catalogued as COSV64222334; called by muse, mutect2, varscan2
- LCN9 | c.177C>T p.F59= | Silent (SNP) | VAF 14/84 reads (17%) | catalogued as rs780893640, COSV52990850; called by muse, mutect2, varscan2
- LDHB | c.99T>A p.G33= | Silent (SNP) | VAF 15/72 reads (21%) | catalogued as COSV63365255; called by muse, mutect2, varscan2
- MAGEC2 | c.864G>A p.E288= | Silent (SNP) | VAF 20/80 reads (25%) | catalogued as rs1040928914, COSV55998842; called by muse, mutect2, varscan2
- MAGEE1 | c.1704C>A p.P568= | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as COSV63911221; called by muse, mutect2, varscan2
- MCM3AP | c.2886C>T p.V962= | Silent (SNP) | VAF 67/195 reads (34%) | catalogued as rs749709980, COSV52442763; called by muse, mutect2, varscan2
- MMP24 | c.1797C>T p.S599= | Silent (SNP) | VAF 19/169 reads (11%) | catalogued as rs779868110, COSV55771754; called by muse, mutect2, varscan2
- MPIG6B | c.684G>A p.A228= (on ENST00000649779 / NM_138272.3; = p.G235R on NM_025260.4) | Silent (SNP) | VAF 35/73 reads (48%) | catalogued as rs376120911; called by muse, mutect2, varscan2
- MUC16 | c.4305T>G p.T1435= | Silent (SNP) | VAF 22/105 reads (21%) | catalogued as COSV67443997; called by muse, mutect2, varscan2
- NCKAP1L | c.3238A>C p.R1080= | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as COSV53209824; called by muse, mutect2, varscan2
- NEFM | c.888C>T p.Y296= | Silent (SNP) | VAF 16/76 reads (21%) | catalogued as rs758993543, COSV55333307; called by muse, varscan2
- NLRX1 | c.648G>A p.V216= | Silent (SNP) | VAF 17/61 reads (28%) | catalogued as COSV52706776; called by muse, mutect2, varscan2
- OGG1 | c.603G>C p.L201= | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as COSV56539592; called by muse, mutect2, varscan2
- OVGP1 | c.1335C>T p.T445= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as COSV63859209; called by muse, mutect2, varscan2
- PADI4 | c.1893C>T p.N631= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as rs370827351; called by muse, mutect2, varscan2
- PITX3 | c.357G>A p.K119= | Silent (SNP) | VAF 4/23 reads (17%) | catalogued as COSV64174741; called by muse, mutect2
- PRB2 | c.267T>G p.P89= | Silent (SNP) | VAF 62/685 reads (9%) | catalogued as COSV66982772, COSV66983518; called by muse, varscan2
- R3HDM1 | c.1029C>T p.S343= | Silent (SNP) | VAF 59/168 reads (35%) | catalogued as COSV51528766; called by muse, mutect2, varscan2
- RIMS2 | c.1269T>A p.S423= (on ENST00000666250 / NM_001348490.2; = p.S231= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 16/95 reads (17%) | catalogued as COSV51651026, COSV51655287, COSV51702036; called by muse, mutect2, varscan2
- RYR3 | c.1119T>G p.T373= | Silent (SNP) | VAF 19/85 reads (22%) | catalogued as COSV101212027, COSV101215037, COSV66780594; called by muse, mutect2, varscan2
- SCARF2 | c.894C>T p.A298= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as COSV56733333; called by muse, mutect2, varscan2
- SUCO | c.3684G>A p.P1228= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as rs767035513, COSV55268487; called by muse, mutect2, varscan2
- THSD7B | c.357C>T p.Y119= | Silent (SNP) | VAF 8/60 reads (13%) | catalogued as rs1455127441, COSV55663354; called by muse, mutect2, varscan2
- TMC3 | c.2796C>A p.V932= | Silent (SNP) | VAF 15/48 reads (31%) | catalogued as COSV63923836; called by muse, mutect2, varscan2
- TNS1 | c.2562T>G p.T854= | Silent (SNP) | VAF 21/127 reads (17%) | catalogued as COSV50729651; called by muse, mutect2, varscan2
- TSHZ3 | c.801G>A p.G267= | Silent (SNP) | VAF 35/160 reads (22%) | catalogued as COSV53676939; called by muse, mutect2, varscan2
- UGT2B15 | c.1155C>T p.I385= | Silent (SNP) | VAF 28/183 reads (15%) | catalogued as COSV57735651; called by muse, mutect2, varscan2
- UPF1 | c.1275G>A p.V425= (on ENST00000599848 / NM_001297549.2; = p.V414= on NM_002911.4) | Silent (SNP) | VAF 26/145 reads (18%) | catalogued as COSV53199040; called by muse, mutect2, varscan2
- WNK2 | c.1161G>A p.L387= | Silent (SNP) | VAF 4/29 reads (14%) | catalogued as COSV52950891; called by muse, mutect2, varscan2
- CCDC34 | c.606+83A>C | Intron (SNP) | VAF 12/38 reads (32%) | catalogued as COSV100156333; called by muse, mutect2, varscan2
- CHD8 | c.6772-264G>A | Intron (SNP) | VAF 14/64 reads (22%) | catalogued as COSV100765232; called by muse, mutect2, varscan2
- KIR3DX1 | n.350G>A | RNA (SNP) | VAF 7/41 reads (17%) | catalogued as rs369642890; called by muse, mutect2, varscan2
- NDUFA10 | c.999+7934G>A | Intron (SNP) | VAF 21/104 reads (20%) | catalogued as COSV99401042; called by muse, mutect2, varscan2
- PTGFRN | c.*1G>T | 3'UTR (SNP) | VAF 21/65 reads (32%) | catalogued as COSV101277216; called by muse, mutect2, varscan2
- TBC1D3F | c.*134G>T | 3'UTR (SNP) | VAF 17/146 reads (12%) | catalogued as rs775371730; called by muse, varscan2
- TTN | c.10360+1253T>G | Intron (SNP) | VAF 19/98 reads (19%) | catalogued as COSV59861821, COSV59870423; called by muse, mutect2, varscan2
- UGT1A6 | c.862-23384G>A | Intron (SNP) | VAF 31/168 reads (18%) | catalogued as rs556129739, COSV59389524; called by muse, mutect2, varscan2
